Somatic mutation profile of tumor specimen 3490835c-c004-45ed-91f3-7c206f (aliquot 3490835c-c004-45ed-91f3-7c206f_D6_2) from CPTAC case 01OV041, project CPTAC-2 (Retroperitoneum and peritoneum — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Peritoneum, NOS; FIGO stage: Stage IIIC.
Specimen 3490835c-c004-45ed-91f3-7c206f: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 98c98aed-ae85-4a7e-8797-52bcf5990755.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 4f43b1d3-ad52-439a-a91e-2e568c (Blood Derived Normal), aliquot 4f43b1d3-ad52-439a-a91e-2e568c_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6ace8aae-fea5-477e-9e9b-74979e647cf8

The open-access MAF lists 88 somatic variants for this specimen: 58 protein-altering or splice-affecting, 18 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 18, Intron 9, Nonsense Mutation 5, Frame Shift Del 3, Splice Region 3, 3'UTR 3, Splice Site 1, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.734C>A p.S245* | Nonsense Mutation (SNP) | VAF 14/152 reads (9%) | catalogued as rs1554076133, COSV57336660; ClinVar: pathogenic; called by muse, mutect2
- ATP13A1 | c.1639G>A p.G547S | Missense Mutation (SNP) | VAF 57/186 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1215996438; called by muse, mutect2, varscan2
- BIRC6 | c.11527G>T p.V3843F | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.41); catalogued as COSV70198728; called by muse, mutect2, varscan2
- CABP7 | c.631C>T p.R211C | Missense Mutation (SNP) | VAF 61/145 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs766203600, COSV53363500; called by muse, mutect2, varscan2
- CALD1 | c.328C>T p.R110C | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs372385136; called by muse, mutect2, varscan2
- CCDC144A | c.2749C>T p.R917C | Missense Mutation (SNP) | VAF 30/178 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs762758123; called by muse, mutect2, varscan2
- CEP162 | c.3094G>A p.D1032N | Missense Mutation (SNP) | VAF 29/228 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0.058); catalogued as rs758112411; called by muse, mutect2, varscan2
- COPA | c.3172C>T p.R1058C | Missense Mutation (SNP) | VAF 46/159 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs772182530; called by muse, mutect2, varscan2
- EPS8L2 | c.1894G>A p.E632K | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.148); catalogued as rs1380250447, COSV59349357; called by muse, mutect2, varscan2
- FAM90A10P | c.785G>A p.R262H | Missense Mutation (SNP) | VAF 196/464 reads (42%) | SIFT tolerated (0.54); PolyPhen benign (0.276); catalogued as rs1453189878; called by muse, mutect2, varscan2
- FRMD4B | c.1576C>G p.L526V | Missense Mutation (SNP) | VAF 33/215 reads (15%) | SIFT tolerated (0.55); PolyPhen benign (0.336); catalogued as rs1475670204; called by muse, mutect2, varscan2
- IGHV3-20 | c.95G>A p.R32Q | Missense Mutation (SNP) | VAF 99/596 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs782117705; called by muse, mutect2, varscan2
- KALRN | c.2944G>C p.E982Q | Missense Mutation (SNP) | VAF 344/647 reads (53%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as COSV99567633; called by muse, mutect2, varscan2
- NHSL2 | c.2044A>C p.T682P (on ENST00000510661; = p.T1048P on NM_001013627.2) | Missense Mutation (SNP) | VAF 60/127 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.189); catalogued as rs1441524399; called by muse, mutect2, varscan2
- OR11H12 | c.26C>G p.T9S | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as COSV73543879; called by muse, mutect2
- PBX3 | c.1138C>T p.H380Y | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.703); catalogued as rs267602132; called by muse, mutect2, varscan2
- PLAT | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 54/86 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99535029; called by muse, mutect2, varscan2
- RAB11B | c.421G>A p.A141T | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.018); catalogued as rs373086696; called by muse, mutect2
- RNF225 | c.80C>G p.S27C | Missense Mutation (SNP) | VAF 90/256 reads (35%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.848); catalogued as COSV52190654; called by muse, varscan2
- RRAS2 | c.71G>A p.G24D | Missense Mutation (SNP) | VAF 130/161 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56329970, COSV56331263; called by muse, mutect2, varscan2
- SCARF1 | c.179C>T p.P60L | Missense Mutation (SNP) | VAF 76/154 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs772819223; called by muse, mutect2, varscan2
- SLC30A3 | c.1154C>G p.P385R | Missense Mutation (SNP) | VAF 98/264 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779570928; called by muse, mutect2, varscan2
- TENM3 | c.7762G>A p.G2588S | Missense Mutation (SNP) | VAF 17/187 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.023); catalogued as rs1203339057, COSV69320674; called by muse, mutect2, varscan2
- ZNF251 | c.1522C>T p.Q508* | Nonsense Mutation (SNP) | VAF 46/304 reads (15%) | catalogued as COSV99478198; called by muse, mutect2, varscan2
- ZNF488 | c.616C>T p.R206* | Nonsense Mutation (SNP) | VAF 47/469 reads (10%) | catalogued as rs376334169; called by muse, mutect2, varscan2
- ZPR1 | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.033); catalogued as rs1274317812, COSV57063792, COSV57064824; called by muse, mutect2
- ZXDA | c.404G>A p.C135Y | Missense Mutation (SNP) | VAF 51/249 reads (20%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.011); catalogued as rs774062078; called by muse, mutect2, varscan2
- AL592490.1 | c.1858G>A p.E620K | Missense Mutation (SNP) | VAF 39/272 reads (14%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- ALOX5 | c.1074T>G p.S358R | Missense Mutation (SNP) | VAF 85/402 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ANKRD28 | c.749G>T p.G250V | Missense Mutation (SNP) | VAF 66/155 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AOPEP | c.2134G>C p.V712L (on ENST00000375315 / NM_001193329.1; = p.V613L on NM_032823.5) | Missense Mutation (SNP) | VAF 24/148 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- ATAD2 | c.1417A>G p.K473E | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATF6B | c.287C>A p.S96Y | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CAMK2G | c.224G>T p.R75L | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CC2D1B | c.1643A>C p.Q548P | Missense Mutation (SNP) | VAF 75/214 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- CD109 | c.4324G>A p.E1442K | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- CD163L1 | c.3803_3826del p.G1268_W1275del | In Frame Del (DEL) | VAF 46/352 reads (13%) | called by mutect2, varscan2
- DHX30 | c.3192-5C>G | Splice Region (SNP) | VAF 20/272 reads (7%) | called by muse, mutect2
- DOCK4 | c.3961T>C p.F1321L | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- FOXL2 | c.1043C>A p.A348D | Missense Mutation (SNP) | VAF 18/138 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.559); called by muse, mutect2, varscan2
- GALE | c.983G>A p.R328K | Missense Mutation (SNP) | VAF 86/560 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- GJA8 | c.661_685del p.V221* | Frame Shift Del (DEL) | VAF 48/434 reads (11%) | called by mutect2, pindel
- GOLGA8Q | c.599G>C p.S200T | Missense Mutation (SNP) | VAF 39/479 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.197); called by muse, mutect2
- GRB7 | c.742C>A p.R248S | Missense Mutation (SNP) | VAF 18/167 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- IGHV3-35 | c.218A>C p.N73T | Missense Mutation (SNP) | VAF 41/856 reads (5%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); called by muse, mutect2
- LMNB2 | c.267G>A p.V89= | Splice Region (SNP) | VAF 117/395 reads (30%) | called by muse, mutect2, varscan2
- NOTCH1 | c.5333C>A p.A1778D | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- OR5L2 | c.902T>A p.L301H | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- PARP14 | c.3701G>T p.G1234V | Missense Mutation (SNP) | VAF 77/131 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- POM121L2 | c.1762_1786del p.K588Sfs*33 | Frame Shift Del (DEL) | VAF 83/474 reads (18%) | called by mutect2, pindel, varscan2
- PRKDC | c.4267del p.I1423* | Frame Shift Del (DEL) | VAF 55/173 reads (32%) | called by mutect2, pindel, varscan2
- RPUSD2 | c.724C>T p.P242S | Missense Mutation (SNP) | VAF 68/328 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SORBS3 | c.1191-7C>G | Splice Region (SNP) | VAF 6/106 reads (6%) | called by muse, mutect2
- TGFBR2 | c.784A>T p.K262* | Nonsense Mutation (SNP) | VAF 93/628 reads (15%) | called by mutect2, varscan2
- TLR6 | c.1550G>C p.S517T | Missense Mutation (SNP) | VAF 47/317 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- TP53 | c.241dup p.T81Nfs*68 | Frame Shift Ins (INS) | VAF 68/181 reads (38%) | called by mutect2, pindel, varscan2
- UBE3D | c.1010+1del p.X337_splice | Splice Site (DEL) | VAF 11/76 reads (14%) | called by mutect2, pindel, varscan2
- ZNF569 | c.848C>A p.S283* | Nonsense Mutation (SNP) | VAF 14/148 reads (9%) | called by muse, mutect2
- ARHGAP32 | c.5166C>T p.N1722= (on ENST00000310343 / NM_001378025.1; = p.N1373= on NM_014715.4) | Silent (SNP) | VAF 143/423 reads (34%) | catalogued as rs368952257, COSV59851181; called by muse, mutect2, varscan2
- CABP1 | c.840T>C p.H280= (on ENST00000316803 / NM_001033677.1; = p.H77= on NM_004276.5) | Silent (SNP) | VAF 17/85 reads (20%) | catalogued as rs763333780; called by muse, mutect2, varscan2
- CCL21 | c.198C>T p.P66= | Silent (SNP) | VAF 62/196 reads (32%) | called by muse, mutect2, varscan2
- CDS2 | c.1071A>C p.A357= | Silent (SNP) | VAF 12/230 reads (5%) | called by muse, mutect2
- COL12A1 | c.6717T>C p.P2239= | Silent (SNP) | VAF 12/89 reads (13%) | called by muse, mutect2, varscan2
- DCLK1 | c.1515G>T p.L505= | Silent (SNP) | VAF 47/182 reads (26%) | called by muse, mutect2, varscan2
- DMAC2 | c.39C>T p.P13= | Silent (SNP) | VAF 42/114 reads (37%) | catalogued as rs781969939; called by muse, mutect2, varscan2
- GPS1 | c.357C>T p.S119= | Silent (SNP) | VAF 22/57 reads (39%) | catalogued as rs549000263; called by muse, mutect2, varscan2
- H1-6 | c.342G>A p.K114= | Silent (SNP) | VAF 37/460 reads (8%) | catalogued as rs768282641, COSV58089898; called by muse, mutect2
- LRPPRC | c.1572A>G p.V524= | Silent (SNP) | VAF 41/190 reads (22%) | called by muse, mutect2, varscan2
- LRRC34 | c.954G>A p.L318= (on ENST00000446859 / NM_001172779.2; = p.L286= on NM_153353.5) | Silent (SNP) | VAF 22/70 reads (31%) | called by muse, mutect2, varscan2
- LRRD1 | c.312T>A p.T104= | Silent (SNP) | VAF 24/210 reads (11%) | called by mutect2, varscan2
- NLRP5 | c.216A>G p.L72= | Silent (SNP) | VAF 22/238 reads (9%) | called by muse, mutect2
- OR2H2 | c.484C>T p.L162= | Silent (SNP) | VAF 90/345 reads (26%) | called by muse, mutect2, varscan2
- P2RX5 | c.381C>T p.G127= | Silent (SNP) | VAF 77/410 reads (19%) | catalogued as rs749859353; called by muse, mutect2, varscan2
- PCDHGA2 | c.1743C>T p.S581= | Silent (SNP) | VAF 108/682 reads (16%) | catalogued as rs1236734969, COSV53903996, COSV99548606; called by muse, mutect2, varscan2
- RNF19A | c.1500C>T p.N500= | Silent (SNP) | VAF 73/470 reads (16%) | called by muse, mutect2, varscan2
- SUPT7L | c.42A>T p.S14= | Silent (SNP) | VAF 22/69 reads (32%) | called by muse, mutect2, varscan2
- ACAD10 | c.3039+83del | Intron (DEL) | VAF 15/110 reads (14%) | called by mutect2, pindel*, varscan2
- ACAD11 | c.1689-113A>G | Intron (SNP) | VAF 19/243 reads (8%) | catalogued as rs1337050202; called by muse, mutect2
- ARHGEF16 | c.805-20C>G | Intron (SNP) | VAF 45/224 reads (20%) | called by muse, mutect2, varscan2
- ARL13B | c.130+703G>A | Intron (SNP) | VAF 14/63 reads (22%) | catalogued as rs1291796384; called by muse, mutect2, varscan2
- CLK4 | c.162-1886G>T | Intron (SNP) | VAF 4/42 reads (10%) | called by muse, mutect2
- DLX1 | c.513+212G>T | Intron (SNP) | VAF 70/152 reads (46%) | called by muse, mutect2, varscan2
- LDHA | c.*515A>C | 3'UTR (SNP) | VAF 27/396 reads (7%) | called by muse, mutect2
- LMF1 | c.1417-315C>T | Intron (SNP) | VAF 104/233 reads (45%) | catalogued as rs897123797; called by muse, mutect2, varscan2
- PTPRH | c.85+17_85+48del | Intron (DEL) | VAF 42/131 reads (32%) | called by mutect2, pindel, varscan2
- SAPCD2 | c.*15G>A | 3'UTR (SNP) | VAF 28/523 reads (5%) | catalogued as rs773842747; called by muse, mutect2
- STK11IP | c.946-23T>C | Intron (SNP) | VAF 42/310 reads (14%) | called by mutect2, varscan2
- TPI1 | c.*283C>T | 3'UTR (SNP) | VAF 89/484 reads (18%) | catalogued as rs1555132871, COSV51290188; called by muse, mutect2, varscan2
